Somatic mutation profile of tumor specimen TCGA-V4-A9ED-01A (aliquot TCGA-V4-A9ED-01A-11D-A39W-08) from TCGA case TCGA-V4-A9ED, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Ciliary body; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 45.3 years (16,528 days).
Specimen TCGA-V4-A9ED-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72f6132a-8656-4f9e-8894-f1a9415d1ec2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9ED-10A (Blood Derived Normal), aliquot TCGA-V4-A9ED-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd9dcb73-a0df-4598-9625-2f4746b9397a

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYSLTR2 | c.386T>A p.L129Q | Missense Mutation (SNP) | VAF 90/214 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56166671; called by muse, mutect2, varscan2
- ETS1 | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 18/114 reads (16%) | catalogued as COSV60091588, COSV60094331; called by muse, mutect2, varscan2
- HSD17B7 | c.665G>C p.C222S | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1436565170; called by muse, mutect2, varscan2
- BCAS1 | c.1506C>G p.D502E | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AMER3 | c.528G>A p.S176= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as rs776935592, COSV58467357, COSV58469465; called by muse, mutect2, varscan2
- ASIC2 | c.372G>A p.P124= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as rs770764384, COSV63332185; called by muse, mutect2, varscan2
- NACA | c.71-4678C>T | Intron (SNP) | VAF 10/18 reads (56%) | called by mutect2, varscan2
